Somatic mutation profile of tumor specimen RC-B6SS-TTP1-A (aliquot RC-B6SS-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SS, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Anaplastic large cell lymphoma, T cell and Null cell type; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 50.7 years (18,503 days).
Specimen RC-B6SS-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 674bb698-53a9-403f-936c-204231c3de90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SS-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SS-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08308de9-6608-45ea-8789-4b657f46c6a7

The open-access MAF lists 216 somatic variants for this specimen: 153 protein-altering or splice-affecting, 52 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 52, Intron 7, Nonsense Mutation 6, Frame Shift Del 4, RNA 2, 5'Flank 1, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 56/177 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 32/149 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD12 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | catalogued as COSV100041981; called by muse, mutect2, varscan2
- ANXA11 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as rs1318489141, COSV55417492; called by muse, mutect2, varscan2
- ARVCF | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs574097179; called by muse, mutect2, varscan2
- BCL11A | c.685C>A p.P229T (on ENST00000335712 / NM_001365609.1; = p.P263T on NM_018014.4) | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs946244619, COSV59623842, COSV59637975; called by muse, mutect2
- C10orf71 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs183879740, COSV100110414, COSV60505553; called by muse, mutect2
- C1QL2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs759334873, COSV55606926; called by muse, mutect2
- C8orf34 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 147/244 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as rs770645498, COSV62064704; called by muse, mutect2, varscan2
- CNTNAP5 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101443891, COSV70500898; called by muse, mutect2, varscan2
- CR2 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs753380303; called by muse, mutect2, varscan2
- DACT3 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV56260962; called by muse, mutect2, varscan2
- DNAH7 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs13034775; called by muse, mutect2, varscan2
- EMD | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs782461599, CD116823; called by muse, mutect2, varscan2
- FAT4 | c.4190G>A p.R1397K | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.958); catalogued as COSV101272887; called by muse, mutect2
- GPR158 | c.2954C>T p.T985I | Missense Mutation (SNP) | VAF 44/441 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs780197706, COSV66265188; called by muse, mutect2
- GRM4 | c.2468C>T p.T823M | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1000580962, COSV100945563; called by muse, mutect2
- IL1RAPL1 | c.191A>T p.Y64F | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56243516; called by muse, mutect2, varscan2
- IQCM | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV72429649; called by muse, mutect2
- LARGE2 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393781940; called by muse, mutect2, varscan2
- LIMS2 | c.634G>A p.A212T (on ENST00000355119 / NM_001161403.3; = p.A236T on NM_017980.4) | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762554883, COSV55755307; called by muse, mutect2, varscan2
- LSM11 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs769770410, COSV53848901; called by muse, mutect2, varscan2
- MFSD14A | c.711A>T p.L237F | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980045697; called by muse, mutect2, varscan2
- MFSD2B | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs770621252; called by muse, mutect2, varscan2
- MGAT3 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100362134; called by muse, mutect2
- NACAD | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 106/210 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs950570302; called by muse, mutect2, varscan2
- NES | c.3430C>G p.L1144V | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV63962601; called by muse, mutect2, varscan2
- NYAP2 | c.1294A>C p.S432R | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV56017933; called by muse, mutect2, varscan2
- OCRL | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV63980894; called by muse, mutect2, varscan2
- OR10J1 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV71129231; called by muse, mutect2, varscan2
- OR4C11 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs781596304; called by mutect2, varscan2
- PBLD | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs753497852; called by muse, mutect2, varscan2
- PCDHB8 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.344); catalogued as COSV50790749; called by muse, mutect2, varscan2
- PIK3R1 | c.1891C>T p.R631* (on ENST00000521381 / NM_181523.3; = p.R361* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 37/181 reads (20%) | catalogued as rs761888083, COSV57134805; called by muse, mutect2, varscan2
- PKP1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376870836; called by muse, mutect2, varscan2
- PKP2 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759920696, COSV50729027; called by muse, mutect2, varscan2
- PLEKHO2 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.286); catalogued as rs748867208, COSV60262078; called by muse, mutect2, varscan2
- PPP4C | c.365A>G p.Q122R | Missense Mutation (SNP) | VAF 113/230 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99661781; called by muse, mutect2, varscan2
- RESF1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as COSV57023642; called by muse, mutect2, varscan2
- RGS22 | c.2360A>G p.K787R | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1160786402; called by muse, mutect2
- ROBO2 | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100170338; called by muse, mutect2, varscan2
- SCN1A | c.2716G>A p.V906M (on ENST00000303395 / NM_001202435.3; = p.V895M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs185760342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A12 | c.864dup p.V289Cfs*26 | Frame Shift Ins (INS) | VAF 32/186 reads (17%) | catalogued as rs1163021209; called by mutect2, pindel, varscan2
- SLC38A3 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs768996943; called by muse, mutect2, varscan2
- SLC38A5 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1398768672; called by muse, mutect2
- SNIP1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV99953151; called by muse, mutect2, varscan2
- SRBD1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs754497325; called by muse, mutect2, varscan2
- STON1 | c.1386G>T p.E462D | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as rs138179455; called by muse, mutect2, varscan2
- TET2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV54427109; called by muse, mutect2, varscan2
- TRERF1 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV61677382; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1607G>T p.R536M | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs750899380, COSV100708777; called by muse, mutect2, varscan2
- TRIP12 | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52266136; called by muse, mutect2
- UNC80 | c.5051C>T p.P1684L | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs961514821, COSV55903978; called by muse, mutect2
- WDFY4 | c.3137C>A p.T1046N | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1357435083; called by muse, mutect2, varscan2
- XKR6 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1308717470; called by muse, mutect2, varscan2
- XYLT1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151118959; called by muse, mutect2, varscan2
- ZNF606 | c.934A>T p.T312S | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV100357284; called by muse, mutect2, varscan2
- ZNF700 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs143985957; called by muse, mutect2, varscan2
- ZNF74 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV62622741; called by muse, mutect2, varscan2
- ABHD8 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, varscan2
- ADGRB1 | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADIRF | c.228A>C p.K76N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AGL | c.3689T>C p.M1230T | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMOTL2 | c.1135A>T p.K379* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ANKRD30B | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARID2 | c.2734C>T p.Q912* | Nonsense Mutation (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- ASCL1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by mutect2, varscan2
- ATP13A3 | c.945C>A p.C315* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- C1QC | c.74G>T p.R25M | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); called by muse, mutect2
- C1orf116 | c.1724T>A p.V575D | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CC2D2B | c.1119del p.K373Nfs*6 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- CFH | c.1013A>G p.E338G | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CNTNAP3B | c.1136G>T p.S379I | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- DLC1 | c.1226C>A p.T409K | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- DSCAM | c.2830T>A p.S944T | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ELOA | c.1795C>G p.P599A | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EPS8 | c.1951C>A p.P651T | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERBIN | c.3527G>T p.R1176M | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FANCB | c.1774A>C p.K592Q | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FER1L6 | c.1243T>C p.F415L | Missense Mutation (SNP) | VAF 25/410 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- FLT4 | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FOXG1 | c.1134C>A p.H378Q | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- GIGYF2 | c.2804C>A p.T935K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- GNPAT | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR155 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC5B | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY2C | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HK3 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFI44L | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- IPO5 | c.2410C>T p.H804Y | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IRX2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ITCH | c.2018del p.G673Dfs*5 (on ENST00000262650 / NM_001257137.3; = p.G632Dfs*5 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/211 reads (12%) | called by mutect2, pindel, varscan2
- KCNH2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by muse, mutect2
- KCNT2 | c.2507T>A p.I836N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KDM4D | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1549 | c.4290_4303del p.D1431Sfs*23 | Frame Shift Del (DEL) | VAF 28/163 reads (17%) | called by mutect2, pindel, varscan2
- LAMA5 | c.5644G>A p.D1882N | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP1B | c.8624C>T p.S2875F | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST3 | c.2167G>T p.A723S | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCCC1 | c.1396A>G p.N466D | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MELTF | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOA1 | c.1585T>G p.F529V | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- OR10S1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 25/490 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- OR8B3 | c.670A>T p.S224C | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- OSBPL8 | c.2644G>A p.V882I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PCDHB13 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- PHF2 | c.1229C>A p.T410K | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PITPNA | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PKD1L1 | c.5878T>A p.S1960T | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PLBD1 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLOD2 | c.1875T>A p.F625L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2
- PLXNB1 | c.5458G>A p.E1820K | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PPP6R3 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCA | c.1223A>C p.Q408P | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN13 | c.6372A>C p.E2124D (on ENST00000411767 / NM_080683.3; = p.E2105D on NM_006264.3) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN18 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRQ | c.3671T>C p.I1224T (on ENST00000616559; = p.I1182T on NM_001145026.2) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PXDN | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- RASAL1 | c.268A>C p.S90R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RASGEF1B | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBFOX1 | c.1181T>C p.F394S | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RECQL4 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2
- RGPD4 | c.4699G>A p.G1567R | Missense Mutation (SNP) | VAF 39/424 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2
- RIN2 | c.2735G>T p.R912L (on ENST00000255006 / NM_001242581.1; = p.R863L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIN3 | c.2892_2894del p.G972del | In Frame Del (DEL) | VAF 45/87 reads (52%) | called by pindel, varscan2*
- RNF182 | c.584G>C p.S195T | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- RPL26 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SCN1A | c.4658T>C p.L1553P (on ENST00000303395 / NM_001202435.3; = p.L1542P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEC61A2 | c.151T>G p.F51V | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2
- SFXN5 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.095); called by muse, mutect2
- SHLD2 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A20 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- SNX7 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SOX9 | c.1366del p.A456Qfs*14 | Frame Shift Del (DEL) | VAF 75/303 reads (25%) | called by mutect2, pindel, varscan2
- SP9 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.344); called by muse, mutect2
- SPATS2L | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPP1 | c.355C>T p.Q119* (on ENST00000395080 / NM_001040058.2; = p.Q105* on NM_000582.2) | Nonsense Mutation (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2, varscan2
- STAG1 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STEAP2 | c.272T>G p.V91G | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STK32B | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SZT2 | c.4510G>C p.E1504Q (on ENST00000634258 / NM_001365999.1; = p.E1447Q on NM_015284.4) | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TDO2 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THOC2 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRIO | c.3773G>A p.S1258N | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- TTC6 | c.1546T>C p.F516L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TUSC1 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- USH2A | c.2563A>C p.I855L | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZFHX3 | c.5495T>A p.L1832Q | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZFHX4 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF257 | c.595A>T p.N199Y | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF514 | c.1194A>C p.K398N | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ZNF662 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN18 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGBL5 | c.2109G>A p.R703= | Silent (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- ALDH16A1 | c.846G>A p.T282= | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as rs202209926, COSV53193088; called by muse, mutect2, varscan2
- ANKS1A | c.2511G>A p.P837= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as rs565747592, COSV64459210; called by muse, mutect2, varscan2
- ARMH1 | c.729C>T p.I243= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as rs1354769531, COSV100679646; called by muse, mutect2, varscan2
- ATP4A | c.1383C>T p.D461= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- ATXN7L1 | c.390C>T p.P130= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as rs993502444; called by muse, mutect2, varscan2
- BIN2 | c.306C>T p.I102= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs1469053591, COSV99909707; called by muse, mutect2, varscan2
- BTBD8 | c.4731A>G p.V1577= (on ENST00000636805 / NM_001376131.1; = p.V1064= on NM_015237.4) | Silent (SNP) | VAF 106/242 reads (44%) | catalogued as rs905427229; called by muse, mutect2, varscan2
- CFAP221 | c.357C>A p.L119= | Silent (SNP) | VAF 40/169 reads (24%) | called by muse, mutect2, varscan2
- CNMD | c.588T>G p.L196= | Silent (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- COL11A1 | c.2067T>C p.P689= | Silent (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- CSMD3 | c.501G>A p.K167= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV52104810; called by muse, mutect2, varscan2
- CST5 | c.142C>T p.L48= | Silent (SNP) | VAF 26/190 reads (14%) | called by muse, mutect2, varscan2
- CYP4A11 | c.648C>A p.S216= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as COSV100152252; called by muse, mutect2, varscan2
- DSP | c.504T>C p.G168= | Silent (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- DYSF | c.3663G>C p.P1221= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV50282744; called by muse, mutect2, varscan2
- EPHA4 | c.687T>C p.V229= | Silent (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- EPS15L1 | c.1728G>C p.L576= | Silent (SNP) | VAF 32/201 reads (16%) | called by muse, mutect2, varscan2
- FAM126B | c.789C>T p.I263= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- FHDC1 | c.1956G>A p.P652= | Silent (SNP) | VAF 64/250 reads (26%) | catalogued as rs144301103; called by muse, mutect2, varscan2
- GPATCH2 | c.1551C>T p.S517= | Silent (SNP) | VAF 35/259 reads (14%) | catalogued as rs369269195; called by muse, mutect2, varscan2
- ITGA11 | c.1570C>T p.L524= | Silent (SNP) | VAF 82/182 reads (45%) | catalogued as rs747147009; called by muse, mutect2, varscan2
- ITIH3 | c.1185T>C p.D395= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs1435944872; called by muse, mutect2, varscan2
- KIF24 | c.591G>T p.G197= | Silent (SNP) | VAF 27/158 reads (17%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.570A>C p.A190= | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- LONRF2 | c.639G>A p.P213= | Silent (SNP) | VAF 29/171 reads (17%) | called by muse, mutect2, varscan2
- MLPH | c.1182C>T p.S394= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs1553601827; called by muse, mutect2, varscan2
- MSS51 | c.207C>T p.S69= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- MYO9B | c.1824G>A p.L608= | Silent (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2, varscan2
- NCOR2 | c.4860C>T p.G1620= | Silent (SNP) | VAF 23/207 reads (11%) | catalogued as rs776029933, COSV62298217, COSV62302663; called by muse, mutect2, varscan2
- NOX1 | c.582G>A p.E194= | Silent (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- NPFFR1 | c.753C>T p.P251= | Silent (SNP) | VAF 49/207 reads (24%) | catalogued as rs1467351421; called by muse, mutect2, varscan2
- NWD1 | c.735G>A p.P245= | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as rs767040114, COSV60341233; called by muse, mutect2, varscan2
- OR10C1 | c.843G>T p.V281= (on ENST00000622521; = p.V279= on NM_013941.3) | Silent (SNP) | VAF 39/389 reads (10%) | catalogued as rs904214490; called by muse, mutect2, varscan2
- PCDH11X | c.123C>T p.G41= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV53456219, COSV53461674; called by muse, mutect2, varscan2
- PCDHA5 | c.1518C>T p.Y506= | Silent (SNP) | VAF 84/437 reads (19%) | called by muse, mutect2, varscan2
- PGP | c.447G>A p.Q149= | Silent (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- PTCHD1 | c.1332C>G p.V444= | Silent (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- SERPINA9 | c.183G>A p.L61= | Silent (SNP) | VAF 73/297 reads (25%) | called by muse, mutect2, varscan2
- SGTA | c.273A>C p.A91= | Silent (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- SH3TC2 | c.870C>T p.Y290= | Silent (SNP) | VAF 58/143 reads (41%) | called by muse, mutect2, varscan2
- SLC26A9 | c.654G>A p.S218= | Silent (SNP) | VAF 29/252 reads (12%) | catalogued as rs368231526; called by muse, mutect2, varscan2
- SLC2A9 | c.882C>T p.R294= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs371115520; called by muse, mutect2, varscan2
- SPG11 | c.3474T>C p.P1158= | Silent (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- TENM2 | c.8073G>A p.E2691= (on ENST00000518659 / NM_001122679.2; = p.E2452= on NM_001080428.3) | Silent (SNP) | VAF 30/216 reads (14%) | called by muse, mutect2, varscan2
- TMEM74B | c.327G>C p.G109= | Silent (SNP) | VAF 50/315 reads (16%) | catalogued as rs747832954; called by muse, mutect2, varscan2
- TP53BP1 | c.4545T>C p.Y1515= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as rs1475542155, COSV55506409; called by muse, mutect2, varscan2
- TTC6 | c.2073T>A p.V691= | Silent (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- TULP2 | c.1413G>A p.S471= | Silent (SNP) | VAF 28/250 reads (11%) | catalogued as rs769061792; called by muse, mutect2, varscan2
- UGT2A1 | c.1242C>T p.N414= | Silent (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- UTP20 | c.7221T>C p.L2407= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.294G>C p.L98= | Silent (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- AC074389.2 | n.77G>A | RNA (SNP) | VAF 17/220 reads (8%) | catalogued as rs1054293285; called by muse, mutect2
- AKAP7 | c.851-28474C>T | Intron (SNP) | VAF 81/146 reads (55%) | catalogued as rs1297616540, COSV99541885; called by muse, mutect2, varscan2
- BID | c.362-588C>T | Intron (SNP) | VAF 30/153 reads (20%) | catalogued as rs771570679; called by muse, mutect2, varscan2
- CHCHD3 | c.369+1150A>C | Intron (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- ENDOG | c.-12C>G | 5'UTR (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-85T>A | Intron (SNP) | VAF 15/105 reads (14%) | catalogued as rs1472693064; called by muse, mutect2, varscan2
- ISCU | c.418+26C>T | Intron (SNP) | VAF 40/180 reads (22%) | called by muse, mutect2, varscan2
- MUC19 | n.6247A>G | RNA (SNP) | VAF 33/173 reads (19%) | catalogued as rs1452662566; called by muse, mutect2, varscan2
- NAT1 | c.-85-2430C>T | Intron (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- NOSTRIN | c.631-102G>A | Intron (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
- RAB3C | chr5:58582399 G>A | 5'Flank (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
